Somatic mutation profile of tumor specimen 0DHZS5 from CCDI case PBBUAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 8.6 years (3,134 days).
Specimen 0DHZS5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1f8a6f6-b6c4-47bf-bf3d-b1b02c3b83d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHZRV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3513003-96c9-4357-98a0-d61ec5dd315a

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.784C>G p.H262D | Missense Mutation (SNP) | VAF 230/798 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.786); called by muse, varscan2
- NAE1 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 372/1022 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, varscan2
